Surgical pathology report (de-identified scan), TCGA case TCGA-36-1581, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-1581-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

TCGA-36-1581

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering Physician:

Final Diagnosis:

A. Left tube and ovary:

- 1) High-grade serous carcinoma of ovary involving serosal surface of tumor.
- 2) Fallopian tube negative for tumor.

B. Omentum: Negative for tumor.

C. Uterus, cervix, right ovary and tube:

- 1) Metastatic high-grade serous carcinoma to uterine serosa.
- 2) Atrophic endometrium.
- 3) Benign uterine leiomyomata.
- 4) Endometriosis of cul-de-sac.
- 5) Unremarkable cervix.
- 6) Right ovary showing involvement by high-grade serous carcinoma, likely metastatic from the opposite ovary.
- 7) Unremarkable right fallopian tube.

Clinical History as Provided by Submitting Physician:

Cytology Report

Large pelvic mass ?Ca. ovary

A. Left tube and ovary (for frozen section)

?Primary or metastatic tumour

B. Omentum

C. Uterus, cervix, right ovary and tube

Specimens Received:

A: left tube and ovary

B: omentum

C: uterus, cervix, right ovary & tube

Gross Description:

Specimen is received in three containers each labelled with the patient's name.

Container "A" is labelled "left tube and ovary" and consists of the fallopian tube measuring 6.5 cm in length and 0.4 cm in diameter. The serosal shows a solid tumour mass measuring 12 x 11 x 8 cm. The external surface shows focal tan-purple hemorrhage and a few fine adhesions that are inked in black. Cross-section of the tumour mass shows a solid tan-white fibrous structure with yellowish nodules with focal hemorrhage and necrosis.

Representative sections are submitted as follows:

[page 2 of 2]
"A1-A2" -frozen section blocks

"A3-A9" -left ovary and tumour relationship with serosal surface

"A10" -fallopian tube

Container "B" is labelled "omentum" and consists of an apron of greater omentum measuring 28 x 13 x 1.2 cm. Cross-section of the omentum shows normal fat. Representative sections are submitted in "B1-B4"

Container "C" is labelled "uterus, cervix, right ovary plus tube" and consists of the same weighing 82 g. The uterus measures 7 cm superior to inferior, 5.4 cm side by side, 3.2 cm anterior to posterior. The serosal surface of the uterus is roughened with coarse adhesions. The right fallopian tube measures 5.5 cm in length and 0.4 cm in diameter. The right ovary measures 2.6 x 2.2 x 1.2 cm. The serosal surface of the right adnexa is roughened with a few coarse adhesions. The cervix measures 2.5 x 3 cm. The mucosa of the exocervix is normal.

The bivalved uterus shows a polyp arising from the posterior wall of the endocervical canal measuring 1.7 x 0.7 cm. The endometrium is even with a thickness of 0.1 cm. Cross-section of the posterior myometrium shows one fibroid nodule measuring 1.5 cm in the greatest dimension. Elsewhere the myometrium is symmetrical with a maximal thickness of 2.2 cm. Cross-section of the right ovary shows a normal structure.

Representative sections are submitted as follows:

"C1" -anterior cervix

"C2" -posterior cervix

"C3" -cul-de-sac

"C4" -anterior isthmus

"C5" -posterior isthmus

Cross-section of the anterior myometrium shows a yellowish fibroid nodule adherent to the external surface of the uterus measuring 0.6 cm in the greater dimension.

"C6-C7" -anterior myometrium and adherent nodule

"C8" -anterior myometrium

"C9-C10" -posterior myometrium

"C11" -fundus

"C12" -right fallopian tube

"C13-C14" -right ovary

Intraoperative Consultation:

FSA/1,2

Gross Description: 12 x 11 x 8 cm mass and attached tube. Solid variegated tumor with hemorrhage and necrosis.

Provisional Diagnosis: FSA1,2. High grade carcinoma, favor primary serous vs. endometrioid ca.

Source: NCI Genomic Data Commons file a383dc82-5642-43cc-b5e0-0d51e24d1811 (TCGA-36-1581.6512EF01-A2FB-4FD8-9E1A-B59855C256DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).